Surgical pathology report (de-identified scan), TCGA case TCGA-05-4415, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4415-01A (Primary Tumor).

/diagnoses:

Both centrally and peripherally there are large manifestations of bronchopulmonary, large-cell and polymorphocellular, in part also giant-cell adenocarcinoma of the left lung with mucin inclusions.

TNM classification on the basis of these samples pT4 pN2 pMX V1 R0, stage IIIB.
C34.3 M8255/3

Comment/supplementary remark:

The assumed primary, central tumor involves upper and lower lobes, with obliteration and stenosis of central bronchus segments and continuous infiltration of parabronchial lymph nodes. The peripheral manifestation is in S6 and leaves the visceral pleura tumor-free. Sample 3.) contains a further lymph node metastasis. The two carcinomas show tumor invasions in small intratumoral blood vessels. The resection margin of the bronchus and vessels and also the hilar resection surface of the main preparation and the lymph nodes of samples 2.) and 4.) to 6.) are tumor-free.

Source: NCI Genomic Data Commons file e986d716-13b0-4fe5-8b5d-d8c33a593c3b (TCGA-05-4415.E8871F29-3623-4975-BE19-BDA98DBBC33B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).